Somatic mutation profile of tumor specimen 0DV4J2 from CCDI case PBCMFK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Germinoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.9 years (5,792 days).
Specimen 0DV4J2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d945dcbc-e484-472f-b39e-5def71d32371.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV4IT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/931a4706-10e1-45b4-b1f7-e18ee6df269e

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 1, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNOT9 | c.259T>C p.S87P | Missense Mutation (SNP) | VAF 269/1439 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1057519956, COSV55299564; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CNRIP1 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 204/938 reads (22%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.998); catalogued as COSV55148540; called by mutect2, varscan2
- KIT | c.2467T>A p.Y823N | Missense Mutation (SNP) | VAF 301/1251 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55388545, COSV55391455, COSV55393442; called by muse, mutect2, varscan2
- RRAS2 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 200/424 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56329700, COSV56329705; called by muse, mutect2, varscan2
- TRIM42 | c.688G>C p.D230H | Missense Mutation (SNP) | VAF 152/767 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53886835; called by muse, mutect2, varscan2
- AIF1 | c.225G>T p.E75D | Missense Mutation (SNP) | VAF 161/871 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- CHD9 | c.1430A>G p.N477S | Missense Mutation (SNP) | VAF 232/1285 reads (18%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYNC1H1 | c.13526T>G p.V4509G | Missense Mutation (SNP) | VAF 105/609 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LRIG1 | c.1179G>T p.K393N | Missense Mutation (SNP) | VAF 52/904 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2
- PTP4A2 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 253/1145 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- URB1 | c.5590A>G p.S1864G | Missense Mutation (SNP) | VAF 150/627 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TET2 | c.2787T>C p.P929= | Silent (SNP) | VAF 233/1008 reads (23%) | called by muse, mutect2, varscan2
- EPHA8 | c.1315+124C>T | Intron (SNP) | VAF 60/626 reads (10%) | called by muse, mutect2
- PSG8 | c.-75C>A | 5'UTR (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2
